Somatic mutation profile of tumor specimen TCGA-09-0365-01A (aliquot TCGA-09-0365-01A-02W-0372-09) from TCGA case TCGA-09-0365, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.4 years (25,703 days).
Specimen TCGA-09-0365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3593cf86-5563-467a-87b4-a3fe654f82ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-0365-10A (Blood Derived Normal), aliquot TCGA-09-0365-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e301e8a-fac7-42a7-b3bb-54742683eb2b

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 5, Splice Site 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 113/117 reads (97%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs749217850, COSV99771151; called by muse, mutect2, varscan2
- ADAR | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs750065985, COSV52715948; called by muse, mutect2, varscan2
- ADARB1 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100653560; called by muse, mutect2, varscan2
- ADGRF5 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs573068708, COSV51941787; called by muse, mutect2, varscan2
- ADNP | c.2942T>G p.V981G | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100823618; called by muse, mutect2, varscan2
- AP3M1 | c.564C>G p.D188E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100786616; called by muse, mutect2, varscan2
- ATP1A3 | c.1977C>A p.N659K (on ENST00000545399 / NM_001256214.2; = p.N646K on NM_152296.5) | Missense Mutation (SNP) | VAF 42/408 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV100131802, COSV57488759; called by muse, mutect2
- ATXN2 | c.3377C>T p.T1126M (on ENST00000550104; = p.T966M on NM_002973.4) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as rs1187452732, COSV66481327, COSV66485831; called by muse, mutect2, varscan2
- CDYL | c.1714G>T p.E572* (on ENST00000328908 / NM_001368125.1; = p.E518* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV59359522; called by muse, mutect2, varscan2
- CLCN1 | c.2960T>A p.I987N | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV100577586; called by muse, mutect2, varscan2
- DSG1 | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs372724391, COSV99935466; called by muse, mutect2, varscan2
- FUBP3 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs777125650, COSV60514731; called by muse, mutect2, varscan2
- GABBR2 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 151/155 reads (97%) | catalogued as COSV99408884; called by muse, mutect2, varscan2
- GABPB2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100927179; called by muse, mutect2, varscan2
- GALNT8 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as rs375631897; called by muse, varscan2
- GALNT8 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs150516489; called by muse, varscan2
- GTPBP10 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs139533783; called by muse, mutect2, varscan2
- HGF | c.1734T>A p.D578E | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99735172; called by muse, mutect2, varscan2
- HRNR | c.2555C>G p.S852* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100912733, COSV64259033; called by muse, mutect2, varscan2
- KDR | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99816451; called by muse, mutect2, varscan2
- LVRN | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as COSV100773267; called by muse, mutect2, varscan2
- MREG | c.338A>C p.E113A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99614731; called by muse, mutect2
- MVP | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs371042454; called by muse, mutect2, varscan2
- OGDH | c.1193C>G p.T398S | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV99758172; called by muse, mutect2, varscan2
- OR4L1 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV59848870; called by muse, mutect2, varscan2
- PGAP4 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs747277975, COSV66388456; called by muse, mutect2, varscan2
- PRDM15 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV54153827, COSV99063593, COSV99519148; called by muse, mutect2, varscan2
- RBM46 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs752720613, COSV55977134; called by muse, mutect2, varscan2
- RGS17 | c.44T>A p.V15E | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.018); catalogued as COSV99242359; called by muse, mutect2, varscan2
- RLF | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 81/317 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs376171628; called by muse, mutect2, varscan2
- RNF138 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs759513121, COSV55235481; called by muse, mutect2, varscan2
- RPUSD4 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.009); catalogued as COSV100028568; called by muse, mutect2, varscan2
- SLC24A5 | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV99981084; called by muse, mutect2, varscan2
- SLIT2 | c.2442A>T p.R814S | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); catalogued as COSV56570074; called by muse, mutect2, varscan2
- TULP3 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101237457, COSV68118181; called by muse, mutect2, varscan2
- UBE2E1 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100135029; called by muse, mutect2, varscan2
- CRTC2 | c.1674+1dup p.X558_splice | Splice Site (INS) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- EFCAB1 | c.470dup p.M157Ifs*4 | Frame Shift Ins (INS) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- ZNF492 | c.1580G>T p.C527F | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTSL1 | c.147C>T p.C49= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs895343655, COSV52807809; called by muse, mutect2, varscan2
- C16orf78 | c.78G>A p.R26= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as COSV54558932; called by muse, mutect2, varscan2
- CLCN1 | c.2961C>T p.I987= | Silent (SNP) | VAF 31/188 reads (16%) | catalogued as COSV100577587; called by muse, mutect2, varscan2
- CPA3 | c.429T>A p.I143= | Silent (SNP) | VAF 81/567 reads (14%) | catalogued as COSV99935892; called by muse, mutect2, varscan2
- PARP10 | c.2430G>A p.G810= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100477567; called by muse, mutect2, varscan2
- PSMA1 | c.594G>A p.T198= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs569675109, COSV67166090; called by muse, mutect2, varscan2
- RLF | c.1146C>G p.L382= | Silent (SNP) | VAF 33/223 reads (15%) | catalogued as COSV101034972; called by muse, mutect2, varscan2
- SCN2A | c.5889C>T p.T1963= | Silent (SNP) | VAF 87/274 reads (32%) | catalogued as rs776509462, COSV99329609; called by muse, mutect2, varscan2
- TRAPPC10 | c.1668C>G p.R556= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as COSV99378066; called by muse, mutect2, varscan2
- UTRN | c.8889C>T p.L2963= | Silent (SNP) | VAF 71/133 reads (53%) | catalogued as COSV100837797; called by muse, mutect2, varscan2
- ZBTB21 | c.1374A>G p.S458= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as COSV100176820; called by muse, mutect2, varscan2
- NFASC | c.2470+2121G>A | Intron (SNP) | VAF 47/298 reads (16%) | catalogued as rs763954143, COSV100362463; called by muse, mutect2, varscan2
